Somatic mutation profile of tumor specimen TCGA-AB-2843-03B (aliquot TCGA-AB-2843-03B-01W-0728-08) from TCGA case TCGA-AB-2843, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, M6 type; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.4 years (28,275 days).
Specimen TCGA-AB-2843-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae8de9a0-6b8f-4baf-87a4-b50f0f7dc1a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2843-11B (Solid Tissue Normal), aliquot TCGA-AB-2843-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27e34f9f-94ee-49f4-9c76-a22178c1724f

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.973C>T p.R325C (on ENST00000399959; = p.R326C on NM_001356.5) | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1555953548, COSV67863531; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 116/330 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- KIT | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV55409209, COSV55420906; called by muse, mutect2, varscan2
- LRRTM2 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV51222959; called by muse, mutect2, varscan2
- MUC5B | c.7268C>T p.T2423M | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs751650644, COSV71590150; called by muse, mutect2, varscan2
- PLCE1 | c.1750C>A p.L584I | Missense Mutation (SNP) | VAF 149/1057 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV53358873, COSV53362667; called by muse, mutect2, varscan2
- SPAM1 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.639); catalogued as rs200074039, COSV56145406; called by muse, mutect2, varscan2
- SYT1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs144005237; called by muse, mutect2, varscan2
- MRC2 | c.4106G>T p.C1369F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TLR4 | c.913_916del p.N305Vfs*2 (on ENST00000355622 / NM_138554.5; = p.N265Vfs*2 on NM_003266.4) | Frame Shift Del (DEL) | VAF 50/116 reads (43%) | called by mutect2, pindel, varscan2
- MYCL | c.525A>T p.V175= | Silent (SNP) | VAF 68/156 reads (44%) | catalogued as COSV65693482; called by muse, mutect2, varscan2
- POLDIP3 | c.234T>C p.L78= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as COSV52809542; called by muse, mutect2, varscan2
- PRKN | c.1029G>A p.P343= | Silent (SNP) | VAF 23/364 reads (6%) | catalogued as rs753655327, COSV58208942, COSV58225784; ClinVar: likely benign; called by muse, mutect2
